Somatic mutation profile of tumor specimen TCGA-V3-A9ZX-01A (aliquot TCGA-V3-A9ZX-01A-11D-A39W-08) from TCGA case TCGA-V3-A9ZX, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.2 years (20,539 days).
Specimen TCGA-V3-A9ZX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b063e9e0-721f-4121-aa60-15e48b48ac28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V3-A9ZX-10A (Blood Derived Normal), aliquot TCGA-V3-A9ZX-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6ba444d-1e57-4657-8cb7-af8e88a61941

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFAP52 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV55349070; called by muse, mutect2, varscan2
- GGA2 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); catalogued as rs1446470734; called by muse, mutect2, varscan2
- GSDME | c.474G>C p.L158F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRAMEF5 | c.1324G>T p.V442L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- C17orf80 | c.1698C>G p.V566= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- TNS2 | c.741C>T p.H247= (on ENST00000314250 / NM_170754.4; = p.H257= on NM_015319.2) | Silent (SNP) | VAF 46/133 reads (35%) | called by muse, mutect2, varscan2
- SPACA6 | chr19:51693260 T>A | 5'Flank (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
